Surgical pathology report (de-identified scan), TCGA case TCGA-32-2495, project TCGA-GBM (Glioblastoma Multiforme), tissue source site St. Joseph's Hospital (AZ), specimen TCGA-32-2495-01A (Primary Tumor).

NEUROPATHOLOGY REPORT

SPECIMEN SOURCE:

1. Left frontal brain tumor (FS)
2. Left frontal brain tumor (permanent)

TCGA-32-2495

CLINICAL DIAGNOSIS:

Left frontal brain tumor

GROSS DESCRIPTION:

1. Received fresh for frozen section are multiple tan-pink soft tissue fragments aggregating to 0.1 x 0.1 x 0.1 cm. A smear preparation is performed. The specimen is then entirely frozen on one chuck.

FROZEN SECTION DIAGNOSIS:

HISTOLOGICALLY LOW GRADE GEMISTOCYTIC NEOPLASM.

The specimen previously frozen subsequently submitted for permanent section.

GROSS DESCRIPTION:

2. Received in formalin, labeled with the patient's name and "left frontal brain tumor", are multiple fragments of tan-pink to red soft tissue aggregating to 1.0 x 0.7 x 0.5 cm. Entirely submitted in one cassette.

MICROSCOPIC DESCRIPTION:

- 1, 2. Sections demonstrate a moderately to markedly hypercellular glial neoplasm. In specimen 1, small gemistocytes predominant. These are also present in specimen 2, but here atypical fibrillary astrocytes are preponderant. Numerous scattered mitotic figures are seen. Whereas microvascular proliferation is not well developed, there are several foci of necrosis, including foci with pseudopalisading.

DIAGNOSIS:

(PROVISIONAL):

- 1, 2. LEFT FRONTAL BRAIN TUMOR, BIOPSY AND RESECTION:
GLIOBLASTOMA.

ADDENDUM NEUROPATHOLOGY REPORT

ADDENDUM DISCUSSION:

Fewer than 10% of the cells are immunoreactive for MGMT and these appear to be almost exclusively endothelial cells.

ADDENDUM DIAGNOSIS:

- 1, 2. LEFT FRONTAL BRAIN TUMOR, BIOPSY AND RESECTION:
GLIOBLASTOMA.
- TUMOR CELLS NEGATIVE FOR MGMT EXPRESSION.

Source: NCI Genomic Data Commons file 6b6787d1-d1f5-4196-86cf-af8cdb6199e4 (TCGA-32-2495.521C3E99-FF9C-4E02-9217-532BE091FAC0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).